Gene-level copy-number profile of tumor specimen TCGA-OR-A5LE-01A from TCGA case TCGA-OR-A5LE, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 14.7 years (5,383 days).
Specimen TCGA-OR-A5LE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.f3e0595b-e839-4c34-b467-56b303181376.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5LE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/601ea992-5b64-4ee1-af2b-a435412c52bf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,039; copy number 2: 45,639; copy number 3: 1,939; copy number 4: 110; copy number 5: 93.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5LE-01A-11D-A29H-01): tumor purity 0.97, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 93 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:93,720,163–93,889,410, 4 genes, copy number 5 (within-gene range 2–5): AL356094.2, AL356094.1, AL391336.2, AL391336.1.
- chr6:99,124,609–100,178,192, 19 genes, copy number 5: MIR548AI, BDH2P1, FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1, PRDM13, Y_RNA, MCHR2, MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1.
- chr6:100,508,194–100,881,372, 1 gene, copy number 5 (within-gene range 3–5): ASCC3.
- chr6:100,881,471–103,003,897, 9 genes, copy number 5: AL133338.1, AL133338.2, GRIK2, ACTG1P18, AP002528.1, AP002530.1, AL357139.2, AL357139.1, Z98755.1.
- chr6:113,969,701–114,471,705, 1 gene, copy number 5 (within-gene range 2–5): HDAC2-AS2.
- chr6:114,055,586–114,343,045, 1 gene, copy number 5 (within-gene range 2–5): HS3ST5.
- chr6:114,220,681–118,710,075, 58 genes, copy number 5: RNA5SP213, DNAJA1P4, AL138830.2, AL138830.1, AL590550.1, RNU6-475P, AL606845.1, LINC02534, FRK, AL357141.1, TPI1P3, NT5DC1, COL10A1, NIP7P3, AL050331.2, TSPYL4, DSE, AL050331.1, TSPYL1, Z84488.1, CBX3P9, KRT18P22, CALHM6-AS1, CALHM6, AL445224.1, TRAPPC3L, CALHM5, CALHM4, RWDD1, RSPH4A, ZUP1, KPNA5, FAM162B, GPRC6A, RFX6, RPS29P13, RNA5SP214, Z98880.1, VGLL2, ROS1, RN7SKP18, RN7SKP51, AL132671.2, RAP1BP3, AL132671.1, DCBLD1, RNU6-253P, GOPC, NEPNP, NUS1, SLC35F1, AL450405.1, AL589993.1, CEP85L, BRD7P3, PLN, Z99496.1, SSXP10.

Autosomal genes at a single copy (total copy number 1): 9,618. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
